Surgical pathology report (de-identified scan), TCGA case TCGA-B8-5551, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-5551-01A (Primary Tumor).

[page 1 of 2]
Case Number :

Collection Date :

Surgical Pathology Report

Diagnosis:

Kidney, right, laparoscopic nephrectomy

Histologic tumor type/subtype: renal cell carcinoma, clear cell type

Sarcomatoid features: not identified

Histologic grade (if applicable): 3 (of 4, Fuhrman classification)

Tumor size (greatest dimension): 5.4 cm diameter

Tumor focality: unifocal

Extent of invasion:

Extra-capsular invasion into perirenal adipose tissue: not identified

Renal sinus: not involved

Major veins: not involved

Ureter: not involved

Venous: not involved

Lymphatic: not involved

Surgical margins:

Perinephric adipose tissue: not involved

Renal vein: not involved

Ureter: not involved

Adrenal gland: not received

Lymph nodes: none received

Other significant findings: patchy chronic interstitial nephritis, fibrosis, and tubular atrophy

AJCC Stage: pT1b pNx pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

a renal mass.

Gross Description:

Specimen fixation: Formalin

Type of specimen: Laparoscopic nephrectomy

Side of specimen: Right

Size and weight of specimen: 700 grams, 26.5 x 14 x 8.7 cm overall nephrectomy specimen is received composed of an 11.7 x 8 x 6 cm kidney, abundant attached perinephric fat and 4 cm of attached ureter.

Orientation: The perinephric fat margin is inked green.

Presence/absence of adrenal gland: Absent

Tumor description/site: The tumor is located in the lateral aspect of the specimen along the posterior edge mid way between the superior and inferior poles. It is a circumscribed lobulated and variegated tan/red to brown/gray lesion with multiple small tumor buds extending into the parenchyma.

Tumor size: 5.4 x 4.3 x 4.0 cm

[page 2 of 2]
Presence/absence of multicentricity: Absent

Confinement/non-confinement to the kidney: Appears confined to the kidney, although it markedly expands the renal capsule. The overlying perinephric fat appears freely movable.

Extent of invasion:

Perirenal adipose tissue: Questionable involvement (A2)

Gerota's fascia: Tumor grossly does not involve

Renal vein: Tumor grossly does not involve

Ureter: Tumor grossly does not involve

Other organs: N/A

Surgical margins:

Perirenal adipose tissue: Within 0.2 cm (A4)

Renal vein: Negative

Renal artery: Negative

Ureter: Negative

Description of kidney away from tumor: The parenchyma is gray/tan and homogeneous with an average cortical thickness of 0.8 cm. The pelvic urothelium is velvety tan/white and grossly unremarkable and the ureter is of normal caliber.

Lymph nodes (hilar): None identified - the sample from the hilar fat is submitted for investigation.

Other significant findings: None

Tissue submitted for special investigations: Tumor and normal are given to tissue procurement.

Digital photograph taken: No

Block Summary:

A1 - Ureter and vascular margin of resection

A2 - Tumor questionable involvement of perinephric fat

A3 - Tumor expanding capsule

A4

A5 - Tumor and adjacent renal parenchyma

A6 - Central tumor

A7 - Normal kidney

A8 - Hilar fat (Brady)

Light Microscopy:

Light microscopic examination is performed by Dr.

Signature

Attending Pathologist: I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 7c810a1a-7166-4e3e-8a4a-a2efa1404bc8 (TCGA-B8-5551.41158DF6-354C-4A82-B072-090605EBFC5E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).